Gene-level copy-number profile of tumor specimen C3N-01349-02 from CPTAC case C3N-01349, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 77.3 years (28,217 days).
Specimen C3N-01349-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 35e72ece-18a5-431b-b0d6-fd7bd6e69550.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01349-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/1ce815ac-dd68-4639-920c-5f6ade72358a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 7,532; copy number 2: 45,969; copy number 3: 4,208; copy number 4: 606; copy number 5: 40; copy number 6: 17; copy number 7: 9; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:54,864,674–54,869,122, 1 gene (within-gene range 0–1): AC051618.1.
- chr19:20,432,552–20,571,095, 2 genes (within-gene range 0–1): AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 67 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,064,533–204,728,106, 26 genes, copy number 5: AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2.
- chr2:113,157,325–113,209,396, 1 gene, copy number 7 (within-gene range 4–7): PSD4.
- chr2:113,211,421–113,515,488, 8 genes, copy number 7: PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961.
- chr3:13,316,235–13,746,638, 7 genes, copy number 5–9: NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620.
- chr8:128,405,269–128,564,679, 1 gene, copy number 5: LINC00824.
- chr10:74,821,610–75,401,246, 18 genes, copy number 5–6 (within-gene range 3–6): AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1.
- chr12:123,289,109–123,409,353, 5 genes, copy number 5: SBNO1, Y_RNA, SBNO1-AS1, MIR8072, KMT5A.
- chr14:81,441,987–81,450,371, 1 gene, copy number 5: LINC02308.

Autosomal genes at a single copy (total copy number 1): 7,311. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
